Somatic mutation profile of tumor specimen 0DVPOP from CCDI case PBCMZU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,404 days).
Specimen 0DVPOP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ac8a596-9f28-4ba6-89a5-06043ed9afe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPPB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe2fbc18-516f-4da2-99c6-4136e788e3cd

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 3, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC35A2 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 239/575 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs587776961, CM132547; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC13A2 | c.232-4C>T | Splice Region (SNP) | VAF 11/290 reads (4%) | called by muse, mutect2
- SMG8 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 145/731 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 40/875 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZSCAN16 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 389/1003 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2
- DCAF12 | c.768G>T p.R256= | Silent (SNP) | VAF 225/560 reads (40%) | called by muse, mutect2, varscan2
- KIAA2012 | c.1740C>T p.T580= | Silent (SNP) | VAF 346/807 reads (43%) | catalogued as rs1326874172; called by muse, mutect2, varscan2
- KLHL23 | c.552C>G p.L184= | Silent (SNP) | VAF 43/1063 reads (4%) | called by muse, mutect2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
- GPR35 | c.-4-58A>G | Intron (SNP) | VAF 73/169 reads (43%) | called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as COSV55814242; called by muse, mutect2
- RCCD1 | c.-28G>A | 5'UTR (SNP) | VAF 34/162 reads (21%) | called by muse, mutect2, varscan2
